FM case AD3305 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Other and unspecified urinary organs.
https://portal.gdc.cancer.gov/cases/5805b09e-3776-47b5-9ba3-d8f435464ec9

Male, 80.7 years: diagnosis not reported by GDC of the urinary system; metastasis biopsied or resected from the urethra. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
